Surgical pathology report (de-identified scan), TCGA case TCGA-DU-7011, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-7011-01A (Primary Tumor).

[page 1 of 2]
PATHOLOGICAL DIAGNOSIS:

- A. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSIES: LOW HISTOLOGICAL GRADE GLIOMA.
- B. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSIES: LOW HISTOLOGICAL GRADE GLIOMA.
- C. BRAIN, AREA OF ENHANCEMENT, EXCISIONAL BIOPSIES: LOW HISTOLOGICAL GRADE GLIOMA.
- D. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSIES: LOW HISTOLOGICAL GRADE GLIOMA.
MIB-1 PROLIFERATION INDEX 1.5% TO 2.0%.
SEE MICROSCOPIC AND COMMENT.
-

Operation/Specimen: Brain, craniotomy.

Clinical History and Pre-Op Dx: [REDACTED] with large brain tumor
with focal area of enhancement.

GROSS PATHOLOGY:

- A. Received fresh, three fragments, 1.9 cm across in aggregate. Soft, tannish-gray, focally hemorrhagic. In total #1 and 2.

INTRAOPERATIVE CONSULTATION: Brain, right frontal: Glioma.

- B. Received fresh, fragment of brain, 2.2 x 1.4 x 1.0 cm. Gray and white matter with 0.8 cm central defect, and grayish semi-firm white matter. In total #3-5.

INTRAOPERATIVE CONSULTATION: Brain, right frontal: Atypical glial cells, no tumor.

- C. "3 and 4," received fresh, one fragment of soft tissue, 1.1 cm across. Soft, tannish-white, focally hemorrhagic. In total #6 and 7.

INTRAOPERATIVE CONSULTATION: Brain, area of enhancement: Glioma and couple of abnormal vessels.

- D. "4," several fragments, 1.1 cm across in aggregate. Brownish-red, soft, focally hemorrhagic. In total #8-12.

MICROSCOPIC: A. Portions of cerebral cortex and adjacent white matter. The white matter appears hypercellular and rarefied. There is a uniform proliferation of astrocytes with star-like cytoplasm. In

[page 2 of 2]
between these cells, there are normal oligodendrocytes and a sprinkling of naked hyperchromatic nuclei, which are usually round or elongated. There are no mitotic figures or microvascular cellular proliferation. The cerebral cortex is unremarkable.

B. Portions of cerebral cortex and white matter. The white matter is extensively rarefied and somewhat hypercellular with a sprinkling of atypical nuclei as described for part A.

C. Portions of cerebral cortex and white matter in which there is a neoplasm similar to that one described for part A and B. However, in this specimen, the tumor appears more cellular, and is infiltrating the cerebral cortex with perineuronal satellitosis. There are also vessels with slight endothelial hyperplasia. Mitotic figures, microvascular cellular proliferation, and necrosis are absent.

D. Portions of cerebral cortex and white matter with neoplasm similar to the one described above. In here, the neoplasm involves the cerebral cortex which is focally completely effaced. In some of these areas the background is very loose, scantily fibrillary, and suggests microcytic change. Again, features of anaplasia are absent.

SPECIAL STAINS: Immunoperoxidase methods for GFAP and MIB-1 were performed on sections from blocks 4, 8 and 11.

The GFAP brings up the diffuse but regular sprinkling of the lesion by star-like plump astrocytes, and a delicate fibrillary background. With the MIB-1 a proliferation index of 1.5% to 2% is determined in the more cellular areas.

COMMENT: In all these specimens there is a low histological grade glial neoplastic proliferation. The neoplastic cells are rounded or elongated hyperchromatic nuclei. The neoplastic cells are diffusely distributed throughout a rarefied brain parenchyma in which there is a prominent proliferation of astrocytes with prominent cytoplasm that resemble gemistocytes. In the area of enhancement, the tumor is more cellular and/or effaces the cerebral cortex. Throughout the tumor mitotic activity and microvascular cellular proliferation are inconspicuous. There are no areas of necrosis. This neoplasm is most likely an oligodendroglioma or mixed oligoastrocytoma. However, it may also be diagnosed as a low grade astrocytoma, perhaps with gemistocytic features, or as a protoplasmic astrocytoma.

Source: NCI Genomic Data Commons file 6408c711-ec24-4bc1-af78-5785bcd2dd7c (TCGA-DU-7011.4F0CBF0F-F9F0-44F4-B498-C0D821DC4F53.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).